Somatic mutation profile of tumor specimen TCGA-MP-A4SY-01A (aliquot TCGA-MP-A4SY-01A-21D-A24P-08) from TCGA case TCGA-MP-A4SY, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 61.5 years (22,448 days).
Specimen TCGA-MP-A4SY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d96a89e-554d-42d2-835e-660ba5f5a325.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MP-A4SY-10A (Blood Derived Normal), aliquot TCGA-MP-A4SY-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c386bb76-de34-4b20-b0c9-f03a8b5047bb

The open-access MAF lists 157 somatic variants for this specimen: 127 protein-altering or splice-affecting, 25 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 25, Nonsense Mutation 8, Splice Site 3, Intron 3, RNA 2, Frame Shift Del 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 7/34 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PAH | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1131691945, COSV100188534; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 14/96 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.3457G>T p.D1153Y (on ENST00000272895 / NM_173076.3; = p.D835Y on NM_015657.3) | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99792702; called by muse, mutect2, varscan2
- ABCA9 | c.3904A>G p.K1302E | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV100383679; called by muse, mutect2, varscan2
- ABL2 | c.316G>A p.E106K (on ENST00000502732 / NM_007314.4; = p.E91K on NM_005158.5) | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV100773115; called by muse, mutect2, varscan2
- ACCS | c.43T>G p.C15G | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV99773064; called by muse, mutect2, varscan2
- ADAM12 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 7/122 reads (6%) | catalogued as COSV100901841; called by muse, mutect2
- ADAM2 | c.2072T>G p.L691* | Nonsense Mutation (SNP) | VAF 43/152 reads (28%) | catalogued as COSV99698084; called by muse, mutect2, varscan2
- ADAMTS4 | c.1143T>G p.N381K | Missense Mutation (SNP) | VAF 7/164 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.712); catalogued as COSV100917629; called by muse, mutect2
- ADGRG4 | c.860C>G p.S287C | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV99797608; called by muse, mutect2, varscan2
- ADGRL3 | c.424G>T p.E142* (on ENST00000506720 / NM_001322402.2; = p.E74* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV101547456; called by muse, mutect2, varscan2
- AKAP11 | c.5360A>G p.D1787G | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338606364, COSV99214503; called by muse, mutect2, varscan2
- ALB | c.1618C>A p.L540I | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.835); catalogued as COSV99892583; called by muse, mutect2, varscan2
- ANKLE2 | c.1100G>T p.C367F | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100514444; called by muse, mutect2, varscan2
- AP1M1 | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as rs374835622; called by muse, mutect2, varscan2
- BANK1 | c.1602G>T p.M534I | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100537009, COSV100537050; called by muse, mutect2, varscan2
- BTN2A1 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV100438847, COSV57003815; called by muse, mutect2, varscan2
- C15orf39 | c.1271A>T p.Q424L | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV100641526; called by muse, mutect2
- C1R | c.2035A>G p.T679A (on ENST00000536053 / NM_001354346.2; = p.T665A on NM_001733.7) | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV101605641; called by muse, mutect2, varscan2
- CDH9 | c.1979A>C p.N660T | Missense Mutation (SNP) | VAF 36/253 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50270199, COSV99163202; called by muse, mutect2, varscan2
- CDHR2 | c.2307G>C p.E769D | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.831); catalogued as COSV56134523, COSV99992317; called by muse, mutect2
- CDON | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs768719226, COSV99702226; called by muse, mutect2, varscan2
- CEP164 | c.3350T>C p.L1117P | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99634716; called by muse, mutect2, varscan2
- CFHR1 | c.815T>C p.I272T | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.85); catalogued as COSV100259069, COSV57626702; called by muse, mutect2, varscan2
- CIT | c.1810A>C p.T604P | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV99951475; called by muse, mutect2, varscan2
- COL12A1 | c.8180G>T p.R2727I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs956926070, COSV100486866; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/61 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as COSV100989866; called by muse, mutect2, varscan2
- DBT | c.1134G>T p.Q378H | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV100923657; called by muse, mutect2
- DMTF1 | c.1444G>C p.E482Q | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV100487562; called by muse, mutect2
- DNMT3L | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV99533541; called by muse, mutect2
- DOCK7 | c.6399G>A p.M2133I (on ENST00000635253 / NM_001367561.1; = p.M2102I on NM_033407.3) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.028); catalogued as COSV99226550; called by muse, mutect2, varscan2
- DTX2 | c.75G>T p.Q25H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.144); catalogued as COSV100184944; called by muse, mutect2, varscan2
- EEF1A1 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100303411, COSV58550679; called by muse, mutect2
- ERCC8 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as COSV99410848; called by muse, varscan2
- FLNA | c.6284A>G p.E2095G (on ENST00000369850 / NM_001110556.2; = p.E2087G on NM_001456.3) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV100775427; called by muse, mutect2
- FST | c.170G>T p.S57I | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV56815692, COSV99887575; called by muse, mutect2, varscan2
- GBP6 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV100969748, COSV65011361; called by muse, mutect2
- GJA3 | c.618C>G p.F206L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99576525, COSV99576577; called by muse, mutect2, varscan2
- GNAI1 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100650675; called by muse, mutect2
- GRIA2 | c.1231C>A p.L411I | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.074); catalogued as COSV52391624, COSV99646328; called by muse, mutect2, varscan2
- H1-0 | c.440A>G p.K147R | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99959987; called by muse, mutect2, varscan2
- H1-5 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 17/215 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100138156; called by muse, mutect2
- HDAC3 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99781596; called by muse, mutect2, varscan2
- HPR | c.1030A>T p.T344S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.954); catalogued as COSV99931093; called by muse, mutect2, varscan2
- HYDIN | c.12077C>T p.A4026V | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.255); catalogued as COSV101125280; called by muse, mutect2, varscan2
- ITGA8 | c.2481G>A p.L827= | Splice Region (SNP) | VAF 11/91 reads (12%) | catalogued as rs1222816365, COSV100959933; called by muse, mutect2, varscan2
- KIF3C | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99268054; called by muse, mutect2
- KIF4A | c.2738A>T p.E913V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV100979671; called by muse, mutect2, varscan2
- LCOR | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.081); catalogued as COSV100603991; called by muse, mutect2
- LMO4 | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100983971; called by muse, mutect2, varscan2
- LRRC41 | c.2319G>T p.W773C | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58442827; called by muse, mutect2
- LRRC7 | c.2417G>A p.W806* (on ENST00000651989 / NM_001370785.2; = p.W773* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 19/254 reads (7%) | catalogued as COSV50491806, COSV99226818; called by muse, mutect2
- MCOLN2 | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99394387; called by muse, mutect2, varscan2
- METTL14 | c.1155G>C p.L385F | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV66310399; called by muse, mutect2
- MTNR1A | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs147539087; called by muse, mutect2, varscan2
- MTO1 | c.6C>G p.F2L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100940595; called by muse, mutect2, varscan2
- MUC16 | c.5735C>A p.P1912H | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs1341364474, COSV101202320; called by muse, mutect2
- MYCBP2 | c.2624-2A>G p.X875_splice (on ENST00000357337; = p.X913_splice on NM_015057.5) | Splice Site (SNP) | VAF 8/76 reads (11%) | catalogued as COSV100632516; called by muse, mutect2
- MYO10 | c.4375A>C p.K1459Q | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.118); catalogued as COSV99946662; called by muse, mutect2
- NBEA | c.4516G>T p.E1506* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100081838; called by muse, mutect2, varscan2
- NBEA | c.7511A>T p.Y2504F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as COSV100085238; called by muse, mutect2, varscan2
- NF1 | c.2836G>T p.D946Y | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100648549; called by muse, mutect2, varscan2
- NFRKB | c.1258G>T p.A420S (on ENST00000446488 / NM_001143835.2; = p.A445S on NM_006165.3) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.857); catalogued as rs1485868360, COSV100451877, COSV100452159; called by muse, mutect2, varscan2
- NGDN | c.184A>T p.M62L | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV101238948; called by muse, mutect2
- NOX5 | c.909A>T p.Q303H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV52990033, COSV99535032; called by muse, mutect2, varscan2
- NR3C1 | c.1666A>T p.T556S | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99197152; called by muse, mutect2
- OGDHL | c.1524C>A p.F508L | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100934592; called by muse, mutect2
- OR11H6 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.551); catalogued as COSV100210016, COSV59645031; called by muse, mutect2, varscan2
- OR1N2 | c.260A>T p.N87I | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101031489; called by muse, mutect2, varscan2
- OR4L1 | c.691C>A p.H231N | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100235971; called by muse, mutect2, varscan2
- PCDH7 | c.2158C>T p.P720S | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62336945; called by muse, mutect2, varscan2
- PDE4B | c.1342G>T p.V448F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100305698, COSV58468886; called by muse, mutect2, varscan2
- PHLDB2 | c.1968A>T p.E656D | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.05); catalogued as COSV101208806; called by muse, mutect2, varscan2
- PKHD1 | c.7044G>T p.M2348I | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs765362134, COSV100585030; called by muse, mutect2, varscan2
- PLCD1 | c.1606G>A p.G536R | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs371877779, COSV99379384; called by muse, mutect2, varscan2
- POT1 | c.1849G>C p.D617H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100714167; called by muse, mutect2, varscan2
- PPP2R5D | c.977T>A p.V326D | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99776710; called by muse, mutect2, varscan2
- PRDM16 | c.2237C>G p.A746G | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99579627; called by muse, mutect2, varscan2
- PRG4 | c.3203T>C p.I1068T | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100798361; called by muse, mutect2
- PTGIS | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747873847, COSV54835206; called by muse, mutect2, varscan2
- PTPRD | c.5146G>T p.A1716S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100647843, COSV61941985; called by mutect2, varscan2
- RCN3 | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.145); catalogued as COSV54543541, COSV99571519; called by muse, mutect2
- RNASEH2A | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1439655973, COSV99677459; called by muse, mutect2
- RP1L1 | c.5537C>A p.P1846Q | Missense Mutation (SNP) | VAF 107/400 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as COSV101223814; called by muse, mutect2, varscan2
- RPAP1 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV100427430, COSV58538686; called by muse, mutect2, varscan2
- SBF2 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs900191960, COSV56312339; called by muse, mutect2, varscan2
- SERPINA6 | c.972G>T p.L324F | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as rs1476045999, COSV100448528; called by muse, mutect2, varscan2
- SESTD1 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 18/123 reads (15%) | catalogued as COSV100091017, COSV58931951; called by muse, mutect2, varscan2
- SETD2 | c.5449G>T p.E1817* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as COSV57442005; called by muse, mutect2, varscan2
- SGMS2 | c.962T>C p.F321S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV100763535; called by muse, varscan2
- SLC20A2 | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs761411962, COSV100646287, COSV60606352; called by muse, varscan2
- SLC4A3 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99813401; called by muse, mutect2
- SLC6A18 | c.1699del p.A567Rfs*? | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as COSV99722672; called by mutect2, pindel, varscan2
- SMARCA4 | c.3730C>G p.R1244G | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV100759401; called by muse, mutect2, varscan2
- SMG1 | c.10709C>G p.S3570* | Nonsense Mutation (SNP) | VAF 9/70 reads (13%) | catalogued as COSV101247055; called by muse, mutect2, varscan2
- SNTG1 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99387058; called by muse, mutect2
- SPATA31E1 | c.2386G>C p.V796L | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV100351266; called by muse, mutect2, varscan2
- SPDYC | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV101017366; called by muse, mutect2, varscan2
- SRFBP1 | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100233095; called by muse, mutect2
- SUMO1 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 38/303 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV101108680, COSV66260836; called by muse, mutect2, varscan2
- SWAP70 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs751145309, COSV100014298; called by muse, mutect2, varscan2
- TG | c.5042G>T p.G1681V | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV99604066; called by muse, mutect2, varscan2
- TMEM184C | c.255-1G>C p.X85_splice | Splice Site (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99669844; called by muse, mutect2, varscan2
- TNFRSF19 | c.771G>C p.E257D | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99947850; called by muse, mutect2
- TP53I11 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV100371062; called by muse, mutect2
- TPX2 | c.977C>A p.P326H | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV100302208; called by muse, mutect2
- TRIM58 | c.1387A>G p.I463V | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100825379; called by muse, mutect2, varscan2
- TRIM69 | c.1282G>A p.D428N (on ENST00000329464 / NM_182985.5; = p.D269N on NM_080745.5) | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100274461; called by muse, mutect2
- TTC13 | c.1076T>A p.M359K | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as COSV100793074; called by muse, mutect2
- TTC21A | c.631G>T p.G211W | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100087840, COSV57188624; called by muse, mutect2, varscan2
- TTN | c.29476G>A p.D9826N (on ENST00000591111; = p.D8899N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/291 reads (6%) | PolyPhen probably damaging (0.998); catalogued as rs1553875406, COSV60195389; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.2128G>T p.D710Y (on ENST00000591111; = p.D664Y on NM_003319.4) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | PolyPhen probably damaging (0.999); catalogued as COSV100636195, COSV59951260; called by muse, mutect2, varscan2
- UBAP2L | c.911C>G p.P304R | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.134); catalogued as COSV99672681; called by muse, mutect2, varscan2
- UNC5D | c.1988C>T p.P663L | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV54809387, COSV99779745; called by muse, mutect2
- USP36 | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs989165767, COSV100361507, COSV100361949; called by muse, mutect2
- USP53 | c.163A>G p.I55V | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.283); catalogued as rs537200720, COSV99917795; called by muse, mutect2, varscan2
- VDAC2 | c.736-1G>A p.X246_splice | Splice Site (SNP) | VAF 7/62 reads (11%) | catalogued as COSV100041183; called by muse, mutect2, varscan2
- VN1R4 | c.92C>A p.S31Y | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.196); catalogued as COSV100237644; called by muse, mutect2
- WDFY3 | c.8894C>T p.P2965L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99886408; called by muse, mutect2, varscan2
- WDR36 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV101540841; called by muse, mutect2, varscan2
- XPR1 | c.542A>T p.E181V | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV100851540; called by muse, mutect2, varscan2
- XRN1 | c.2668A>T p.S890C | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV99379186; called by muse, mutect2, varscan2
- ZNF266 | c.301A>T p.N101Y | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV100749466; called by muse, mutect2, varscan2
- ZNF304 | c.1711A>G p.S571G | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV99988935; called by muse, mutect2, varscan2
- ZNF33B | c.1295A>T p.Q432L | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100847824; called by muse, mutect2
- ZNF366 | c.2066A>T p.Q689L | Missense Mutation (SNP) | VAF 80/297 reads (27%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100574607; called by muse, mutect2, varscan2
- ADAMTS12 | c.4374A>G p.T1458= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as rs776472308, COSV100711814; called by muse, mutect2, varscan2
- ADAMTS18 | c.1380C>A p.I460= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV51399424, COSV51399690; called by muse, mutect2, varscan2
- ADGRB3 | c.1569G>T p.V523= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV101002111; called by muse, mutect2, varscan2
- AP1B1 | c.2106C>G p.L702= | Silent (SNP) | VAF 12/176 reads (7%) | catalogued as COSV100434256, COSV100434923; called by muse, mutect2
- AQP11 | c.243C>T p.L81= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as rs1188264739, COSV100547427, COSV57992781; called by muse, mutect2, varscan2
- ATP8A2 | c.2565A>G p.A855= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs775277527, COSV99685000; called by muse, mutect2, varscan2
- C1orf56 | c.987G>A p.V329= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as rs1468307071, COSV54847686, COSV99764875; called by muse, mutect2
- CHD1 | c.2337C>G p.A779= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV99400087; called by muse, mutect2, varscan2
- CIDEC | c.309G>T p.G103= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as COSV100396785; called by muse, mutect2
- CLEC4F | c.552G>A p.K184= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as rs782706345, COSV55480649, COSV99714093, COSV99714102; called by muse, mutect2, varscan2
- DPP6 | c.909A>T p.A303= (on ENST00000377770 / NM_001364500.2; = p.A241= on NM_001936.5) | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as rs1245712710, COSV100129025; called by muse, mutect2
- ELP1 | c.318G>A p.G106= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV101010557; called by muse, mutect2, varscan2
- F13B | c.891A>T p.I297= | Silent (SNP) | VAF 39/145 reads (27%) | catalogued as COSV100803540; called by muse, mutect2, varscan2
- GRM5 | c.2265C>T p.T755= | Silent (SNP) | VAF 17/155 reads (11%) | catalogued as COSV100555108; called by muse, mutect2, varscan2
- HYDIN | c.345C>G p.V115= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as rs143520327, COSV99865267; called by muse, mutect2
- IGHV3-13 | c.111G>C p.L37= | Silent (SNP) | VAF 31/214 reads (14%) | called by muse, mutect2, varscan2
- MMP17 | c.1257C>T p.R419= | Silent (SNP) | VAF 24/134 reads (18%) | catalogued as COSV100862004; called by muse, mutect2, varscan2
- OR1C1 | c.375G>T p.A125= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as rs1045359996, COSV101376298, COSV68715720; called by muse, mutect2
- PCDH17 | c.2232C>A p.I744= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs769907429, COSV100932226, COSV64978049; called by mutect2, varscan2
- PDZD2 | c.6663G>A p.R2221= | Silent (SNP) | VAF 37/564 reads (7%) | catalogued as COSV99227304; called by muse, mutect2
- POT1 | c.1848A>T p.T616= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100714168; called by muse, mutect2, varscan2
- POTEH | c.111G>T p.G37= | Silent (SNP) | VAF 46/540 reads (9%) | catalogued as COSV100624635; called by muse, mutect2
- PTBP2 | c.1284G>A p.E428= (on ENST00000426398 / NM_001300986.2; = p.E420= on NM_021190.4) | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as COSV100930305; called by muse, mutect2
- SEMA3E | c.450T>C p.H150= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV100319898; called by muse, mutect2, varscan2
- ZNF44 | c.837T>C p.S279= (on ENST00000356109 / NM_001164276.2; = p.S231= on NM_016264.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 20/228 reads (9%) | catalogued as COSV100633560; called by muse, mutect2
- FOLH1B | n.1024G>T | RNA (SNP) | VAF 6/117 reads (5%) | called by muse, mutect2
- MGAM | c.4618+1252G>C | Intron (SNP) | VAF 8/110 reads (7%) | catalogued as COSV101527663; called by muse, mutect2
- MIR296 | n.29T>A | RNA (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2, varscan2
- NCAPD2 | c.262+240T>G | Intron (SNP) | VAF 9/248 reads (4%) | catalogued as COSV100217528; called by muse, mutect2
- PRR22 | c.194-25C>G | Intron (SNP) | VAF 7/139 reads (5%) | catalogued as COSV100288233, COSV100288570; called by muse, mutect2
